Somatic mutation profile of tumor specimen BA2547D (aliquot aq-BA2547D) from BEATAML1.0 case 2439, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,475 days).
Specimen BA2547D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 045c3795-854e-424d-a8be-a413b19b4f48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2419D (Solid Tissue Normal), aliquot aq-BA2419D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b0d0816-ba4a-4195-be95-a5e7e418e087

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Site 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 72/169 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 33/58 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2
- ADAMTS17 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as rs773895033; called by muse, mutect2, varscan2
- CCNP | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55687679; called by muse, mutect2
- DAAM2 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99225131; called by muse, mutect2, varscan2
- HIF3A | c.130G>A p.A44T (on ENST00000377670 / NM_152795.4; = p.S23= on NM_022462.4) | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs960735275, COSV52205979; called by muse, mutect2, varscan2
- MED16 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1170876513, COSV54129553; called by muse, mutect2
- NFE2L3 | c.1184T>C p.M395T | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs766188564; called by muse, mutect2, varscan2
- OR1N2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs754685404, COSV65460465; called by mutect2, varscan2
- APBB1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.189); called by muse, mutect2
- BRPF3 | c.1603C>A p.Q535K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2
- KAT2B | c.1868C>G p.S623C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH11 | c.5171+1G>A p.X1724_splice | Splice Site (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- PPP2CB | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- WDR36 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAAP20 | c.393G>A p.R131= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- KLHDC7A | c.2088C>T p.S696= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs374490254; called by muse, mutect2, varscan2
- RASGEF1C | c.582C>T p.L194= | Silent (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- EIF2B5 | c.1327-21del | Intron (DEL) | VAF 31/107 reads (29%) | called by mutect2, varscan2
